Surgical pathology report (de-identified scan), TCGA case TCGA-24-2290, project TCGA-OV (Ovarian Serous Cystadenocarcinoma), tissue source site Washington University, specimen TCGA-24-2290-01A (Primary Tumor).

[page 1 of 5]
Name: [REDACTED]
Address: [REDACTED]

MR No.: [REDACTED]
Service: [REDACTED]
Surgeon: [REDACTED]

Surg. Path. No.:
DOB:
Sex/Race:
Location:
Hosp. No.:
Taken/Received:

TCGA-24-2290

DIAGNOSIS

- OMENTUM, OMENTECTOMY - PAPILLARY SEROUS ADENOCARCINOMA
- UTERUS, CERVIX, ABDOMINAL HYSTERECTOMY
- NO HISTOPATHOLOGIC ABNORMALITY
- UTERUS, ENDOMETRIUM, ABDOMINAL HYSTERECTOMY
- ENDOMETRIAL POLYPS
- UTERUS, MYOMETRIUM, ABDOMINAL HYSTERECTOMY
- NO HISTOPATHOLOGIC ABNORMALITY
- UTERUS, SEROSA, ABDOMINAL HYSTERECTOMY
- PAPILLARY SEROUS ADENOCARCINOMA
- OVARY, LEFT, SALPINGO-OOPHORECTOMY
- PAPILLARY SEROUS ADENOCARCINOMA
- OVARY, RIGHT, SALPINGO-OOPHORECTOMY
- PAPILLARY SEROUS ADENOCARCINOMA
- FALLOPIAN TUBE, LEFT, SALPINGO-OOPHORECTOMY
- PAPILLARY SEROUS ADENOCARCINOMA
INVOLVING PERITUBAL SOFT TISSUE
- FALLOPIAN TUBE, RIGHT, SALPINGO-OOPHORECTOMY
- PAPILLARY SEROUS ADENOCARCINOMA
INVOLVING PERITUBAL SOFT TISSUE
- SOFT TISSUE, CUL-DE-SAC, NODULE, EXCISION (FS1)
- PAPILLARY SEROUS ADENOCARCINOMA
- SOFT TISSUE, CUL-DE-SAC, NODULE, EXCISION
- PAPILLARY SEROUS ADENOCARCINOMA
- APPENDIX, APPENDECTOMY - PAPILLARY SEROUS ADENOCARCINOMA

By this signature, I attest that the
above diagnosis is based upon my

[page 2 of 5]
[REDACTED]

[REDACTED]

[REDACTED]

[REDACTED]

[REDACTED]

Surg. Path. No.:

DIAGNOSIS (continued)

personal examination of the slides
(and/or other material indicated in
the diagnosis), and that I have
reviewed and approved this report.

[REDACTED]

[REDACTED]

SPECIMEN(S) SUBMITTED

- Part 1: FS1-CUL DE SAC NODULE
- Part 2: UTERUS, OVARIES, CERVIX, TUBES
- Part 3: CUL DE SAC NODULE
- Part 4: APPENDIX
- Part 5: OMENTUM

HISTORY

The patient is a [REDACTED] with ovarian carcinoma.
Operative procedure: Examination under anesthesia, adhesiolysis,
tumor debulking, TAH/BSO and appendectomy.

An intraoperative non-microscopic consultation was obtained and
interpreted as: "Received fresh in OR is a uterus attached to an
ovary. Opened laterally to show a generally soft, smooth
endometrial surface with a 1.5 cm sessile polyp on the posterior
surface. Tissue donated for GOG. Fixed in formalin." [REDACTED]

FROZEN

- FS: Cul-de-sac nodule and biopsy
- "Adenocarcinoma, poorly differentiated
favor mullerian primary." [REDACTED]

GROSS

The specimens are received in 5 containers of formalin, each
labeled with the patient's name. The first container is labeled

[page 3 of 5]
Name:

Surg. Path. No

Specimen (continued)

cul-de-sac nodule" and contains two fragments of tan-yellow, soft tissue with black ink, measuring 1.7 x 1.0 x 0.2 cm. Labeled FS1

The second container is labeled "uterus, ovaries, cervix and tubes" and contains a previously opened uterus with attached bilateral adnexa weighing 88.5 gm. The uterus measures 6.5 cm superior to inferior by 4 cm anterior to posterior by 3.5 cm cornu-to-cornu. The cervix measures 2.7 x 2.7 x 2.7 cm and the os measures 0.5 cm in diameter. The mucosa of the posterior endocervical canal, measuring 2.2 x 0.5 x 0.2 cm, and a portion of anterior endometrium measuring 1.5 x 0.7 x 0.7 cm, has been removed prior to receipt. The cervix and endocervical canal are otherwise grossly unremarkable. The endometrium shows a white, firm, sessile polyp measuring 1.5 x 1.3 cm on the posterior wall. In addition, there is a pedunculated polyp measuring 0.7 x 0.5 x 0.3 cm at the anterior right superior aspect of the endometrium. The remainder of the endometrium measures 0.1 cm in thickness. The myometrium is grossly unremarkable and measures 1.4 cm in thickness. The anterior serosal surface of the uterus is diffusely involved by firm, white tumor that focally appears to invade the serosal surface of the myometrium. The anterior serosal surface shows focal hemorrhage but no gross tumor.

The right fallopian tube measures 5.5 cm in length and 0.6 cm in diameter. A nodule of tan-white tumor is present in the paratubal soft tissue in the proximal third of the fallopian tube. It measures 1.1 cm in maximum diameter. The right ovary measures 2.7 x 1.4 x 1.4 cm. Sections show a tan-white nodule measuring 0.7 cm in diameter that is grossly suspicious for tumor. The left fallopian tube measures 5.8 cm in length and 0.6 cm in diameter.

[page 4 of 5]
[REDACTED] [REDACTED] [REDACTED]

fallopian tube that measures 0.8 x 0.3 x 0.3 cm. The left ovary measures 3.0 x 2.0 x 1.5 cm. The serosal surface is irregular and grossly suspicious for involvement by tumor. Sections show gross involvement by tan-white tumor extending to the surface. The ovaries are submitted in their entirety. Labeled: CX1 - posterior cervix; CX2 - anterior cervix; EM1 and EM2 - posterior endometrium with sessile polyp; EM3 and EM4 - anterior endometrium with serosal tumors (EM4 also with pedunculated polyp). CX1 and EM1, as well as CX2 and EM3 represent continuous sections. LT - left fallopian tube; RT - right fallopian tube; L0 and L02 - left ovary; R0, R02, R03, R04, R05 - right ovary. [REDACTED]

--3--

Name: [REDACTED]

GROSS (continued)

The third container is labeled "cul-de-sac nodule" and contains multiple fragments of tan-white, friable tissue, measuring 3.0 x 2.0 x 0.5 cm in aggregate. [REDACTED]

The fourth container is labeled "appendix" and contains an appendix measuring 7 cm in length and 0.6 cm in proximal diameter. The distal tip of the appendix is expanded by tan-white tumor, measuring 2.5 x 2.4 x 2.8 cm. The mid portion of the appendix shows fibrous obliteration and a diameter of 0.2 cm over approximately 1 cm of its length. [REDACTED]

The fifth container is labeled "omentum" and contains a portion of omentum measuring 23 x 8 x 4.5 cm. Tumor grossly involves the great majority of the fibroadipose tissue with multiple nodules as well as diffuse infiltration of fat. Much of the surface of the omentum appears hemorrhagic. [REDACTED]

COMMENT

[page 5 of 5]
[REDACTED]

The omentum is diffusely replaced by poorly differentiated papillary serous adenocarcinoma. Adenocarcinoma with identical histologic features is also present on the serosal surface of the uterus, in peritubal soft tissue, in the cul-de-sac nodule, and around the appendix. Histologically identical adenocarcinoma also extensively involves the surfaces of the entirely submitted ovaries. Carcinoma focally extends into the superficial cortex of the ovaries and a single, 3 mm nodule of adenocarcinoma is present within the parenchyma of one ovary. Because none of the non-surface ovarian involvement measures more than 5 mm, according to [REDACTED] criteria, this case should be considered a primary peritoneal carcinoma.

nd of Report)

Source: NCI Genomic Data Commons file 398495bc-8825-4f1e-833b-4e3c52a17d59 (TCGA-24-2290.71036F77-0D99-427A-883C-75624453890D.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).